Somatic mutation profile of tumor specimen BA2025D (aliquot aq-BA2025D) from BEATAML1.0 case 2429, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.7 years (11,205 days).
Specimen BA2025D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82a498a9-5190-4c62-a14c-02639da54e60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3016D (Solid Tissue Normal), aliquot aq-BA3016D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ea0c291-8b4e-40cf-b8a5-845232c412f0

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 5'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYBBP1A | c.3460G>T p.A1154S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV99627018; called by muse, mutect2
- SHANK2 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs782002202, COSV58325993; called by muse, mutect2, varscan2
- AHDC1 | c.3882G>T p.K1294N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CGNL1 | c.1395C>A p.N465K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- CHRM1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2
- KIAA2012 | c.3271C>T p.R1091* | Nonsense Mutation (SNP) | VAF 70/200 reads (35%) | called by muse, varscan2
- ZBTB20 | c.1237G>T p.A413S (on ENST00000474710 / NM_001164342.2; = p.A340S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- SRPK1 | c.735G>T p.P245= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- STEAP3 | c.213G>A p.A71= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs372757046; called by muse, mutect2, varscan2
- UNC93A | c.981G>A p.A327= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs753203183, COSV57809171; called by muse, mutect2, varscan2
- ZNF461 | c.159C>T p.A53= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as rs779475299, COSV64454353; called by muse, mutect2, varscan2
- BEND5 | c.-31G>T | 5'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- SPATA13 | c.-222-25508C>A | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs1400345471; called by muse, mutect2
